Somatic mutation profile of tumor specimen MMRF_1778_1_BM_CD138pos (aliquot MMRF_1778_1_BM_CD138pos_T1_KBS5U_K11890) from MMRF case MMRF_1778, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,272 days).
Specimen MMRF_1778_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5e00629-6db8-4336-bbcc-ca1e1111709f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1778_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1778_1_PB_CD3pos_C2_KBS5U_K11909; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d159e9a-1a77-46e4-83ef-db507290d477

The open-access MAF lists 70 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 19, Intron 9, Silent 7, 5'UTR 4, 3'Flank 1, RNA 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKQ | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768749690; called by muse, varscan2
- GALNT5 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs768853895; called by muse, mutect2
- H3C11 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 91/175 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100137751, COSV58899594; called by muse, mutect2, varscan2
- HMGXB3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1004708591; called by muse, mutect2
- HOXD12 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs749162512; called by muse, mutect2, varscan2
- IGSF9B | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58065229; called by muse, mutect2, varscan2
- IKBKB | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100645808, COSV60598802, COSV60598896; called by muse, mutect2, varscan2
- MNT | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs878870582; called by muse, mutect2
- PIGR | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as rs767071176; called by muse, mutect2, varscan2
- PPIE | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1054552682; called by muse, mutect2, varscan2
- SLC6A2 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54923281; called by mutect2, varscan2
- SPHK1 | c.625C>T p.R209* (on ENST00000392496 / NM_001355139.2; = p.R223* on NM_021972.4) | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs1185092590; called by muse, mutect2, varscan2
- TACC2 | c.5075C>T p.P1692L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs780520493; called by muse, mutect2, varscan2
- UTP18 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs539214309, COSV56583294; called by muse, mutect2, varscan2
- WDR70 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs774647806; called by muse, mutect2, varscan2
- YEATS4 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1464980352; called by muse, mutect2, varscan2
- CYP51A1 | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CYTH3 | c.1111_1113del p.E371del (on ENST00000396741; = p.E370del on NM_004227.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 24/46 reads (52%) | called by pindel, varscan2
- HOOK2 | c.1844A>T p.E615V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MOB1B | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEMP2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NPC1L1 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OSR1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PPM1K | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SIM1 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THBS2 | c.637T>G p.F213V | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRAF3 | c.1486del p.L496Sfs*3 | Frame Shift Del (DEL) | VAF 45/67 reads (67%) | called by mutect2, pindel, varscan2
- UBR4 | c.13314G>A p.M4438I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- AGBL4 | c.807C>T p.L269= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- GKN1 | c.126C>G p.V42= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100933563; called by muse, mutect2, varscan2
- IGLV2-14 | c.333A>T p.S111= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- PCDHA2 | c.1869C>T p.R623= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as rs1554120147; called by muse, mutect2, varscan2
- PRL | c.367C>T p.L123= | Silent (SNP) | VAF 51/87 reads (59%) | called by muse, mutect2, varscan2
- SLC22A15 | c.114C>T p.L38= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- WDR88 | c.948G>A p.L316= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- ADAM12 | c.*4136G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.*1195G>A | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- AK9 | c.3633+1121T>C | Intron (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2
- AL589674.1 | n.221G>A | RNA (SNP) | VAF 29/57 reads (51%) | catalogued as rs1236688484; called by muse, mutect2, varscan2
- ANK2 | c.11859+1327G>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- ANKRD13A | c.*1861G>A | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8444C>G | Intron (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- BMP7 | c.*2028C>T | 3'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs904805236; called by mutect2, varscan2
- BTBD19 | c.*343C>A | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- CD44 | c.*1772C>G | 3'UTR (SNP) | VAF 27/27 reads (100%) | called by muse, mutect2, varscan2
- DCN | c.885+593C>T | Intron (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*1635_*1645del | 3'UTR (DEL) | VAF 23/32 reads (72%) | called by mutect2, varscan2
- EFCAB14 | c.987+73G>C | Intron (SNP) | VAF 35/75 reads (47%) | called by mutect2, varscan2
- EHF | c.343+122C>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FCMR | c.*1619G>A | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- GPR132 | c.*48C>T | 3'UTR (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- IL17F | c.34-16G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs1035175728, COSV60233630; called by muse, mutect2, varscan2
- KAZN | c.1222+1422C>A | Intron (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- KCNMA1 | chr10:77638137 G>T | 5'Flank (SNP) | VAF 75/144 reads (52%) | catalogued as rs933872661; called by muse, varscan2
- KRT6B | c.*401C>T | 3'UTR (SNP) | VAF 57/110 reads (52%) | catalogued as rs1383756347; called by muse, mutect2, varscan2
- LNPEP | c.*5783C>T | 3'UTR (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- MPZL1 | c.*448G>C | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- NLN | c.*3264G>C | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- NUAK1 | c.*1867C>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- PHF13 | c.-98C>T | 5'UTR (SNP) | VAF 8/23 reads (35%) | called by mutect2, varscan2
- PLRG1 | c.*400G>A | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- RGS16 | c.*836C>G | 3'UTR (SNP) | VAF 42/146 reads (29%) | called by muse, varscan2
- RNF113B | c.-24C>A | 5'UTR (SNP) | VAF 26/51 reads (51%) | catalogued as COSV99940332; called by muse, mutect2, varscan2
- RSPH6A | c.-118C>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- SLC44A1 | c.*5385G>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs56199933; called by muse, varscan2
- SOS2 | c.*351G>A | 3'UTR (SNP) | VAF 37/68 reads (54%) | catalogued as rs1299738137; called by muse, mutect2, varscan2
- STARD7 | c.-31G>A | 5'UTR (SNP) | VAF 13/23 reads (57%) | catalogued as rs1043382879; called by muse, mutect2, varscan2
- SYNCRIP | chr6:85611814 A>C | 3'Flank (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- TUFT1 | c.415-39C>T | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ZEB2 | c.*875A>T | 3'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as COSV57956723; called by muse, mutect2, varscan2
